Somatic mutation profile of tumor specimen TCGA-AC-A3QQ-01B (aliquot TCGA-AC-A3QQ-01B-06D-A22N-09) from TCGA case TCGA-AC-A3QQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 54.0 years (19,723 days).
Specimen TCGA-AC-A3QQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ae8416a-b546-462d-b821-75883bea825a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A3QQ-10A (Blood Derived Normal), aliquot TCGA-AC-A3QQ-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2db2886-5955-431e-b98d-c5ab5d021c6a

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- C2 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100191255, COSV54961650; called by mutect2, varscan2
- CBFB | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52000610, COSV99325828; called by muse, mutect2, varscan2
- COL6A3 | c.8020T>G p.S2674A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.339); catalogued as COSV99799600; called by muse, mutect2, varscan2
- CWH43 | c.1338T>A p.S446R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99893653; called by muse, mutect2, varscan2
- DNAAF3 | c.68T>A p.L23Q (on ENST00000524407 / NM_001256715.2; = p.L70Q on NM_178837.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100845920; called by muse, mutect2, varscan2
- FTHL17 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as COSV63267733; called by muse, mutect2, varscan2
- RNF144A | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs545761424, COSV57979881; called by muse, mutect2, varscan2
- TTN | c.12592A>T p.K4198* (on ENST00000591111; = p.K4152* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100619980; called by mutect2, varscan2
- TYRO3 | c.1805T>A p.I602N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99777811; called by muse, mutect2, varscan2
- CCNO | c.990del p.L331* | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- L3MBTL3 | c.2121A>T p.K707N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- LPCAT3 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0); called by mutect2, varscan2
- FBP1 | c.460C>T p.L154= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs539871294, COSV100941281; called by mutect2, varscan2
- RPUSD4 | c.1035T>G p.L345= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100028799; called by muse, mutect2, varscan2
